Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RR, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RR-01A (Primary Tumor).

[page 1 of 2]
Nature of material: Brain

Received on:

Macroscopy:

Received three bottles so identified and containing:

- Bottle 1: ("superficial part of the tumor"): three fragments of brain parenchyma measuring together 3.3 x 3.2 x 1.2 cm. To the cuts, there is crisp corticomedullary limit.
- Bottle 2: ("deep part of the tumor"): irregular fragment of light brown and soft tissue, measuring 1.3 x 1.0 x 0.9 cm.
- Bottle 3: ("hypervascular tumor part"): irregular fragment of light brown and soft tissue, measuring 1.5 x 1.4 x 1.2 cm.

Microscopy:

The histological material of 3 bottles show hypercellular glial neoplasm composed of cells with distinct phenotypes. One cell type is represented by cells with irregular nuclei and homogeneously hyperchromatic. The other is formed by cells with rounded to oval nuclei with dispersed chromatin. Both show atypia and evident pleomorphism. It was also observed areas of cells with minigemistocistic pattern. It is note frequent mitotic figures, especially in the areas of cellular injury. Are still observed some scattered foci of dystrophic microcalcifications. There are no evident foci of necrosis or microvascular proliferation in this material.

Diagnosis:

Excision product of lesion in the right parietal lobe:

- Anaplastic oligoastrocitoma (grade III - WHO, 2007).

PROFESSIONAL PARTICIPANTS OF REPORT

Pr TSS, dx discrepancy from
States TCGA tumor to be
grade II, (not grade III).
BCR

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:

Study/Site: TCGA Brain lower grade glioma -

(Brain Lower Grade Glioma)

Event: PathDiscrepancy

Interviewer:

Person ID: N/A

Age: N/A

Date of Birth:

Sex: M

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report

Oligoastrocytoma grade III

Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF

Oligoastrocytoma grade II

Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

wrote in TCGA Pathologic Diagnosis Discrepancy Form: "In my opinion there is no criteria for grade III in this tumor. The case iniatialy seen by other pathologist".

Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file e4a9c928-d3e0-485f-bd47-42eda95fb283 (TCGA-TQ-A7RR.34C9D741-8075-4FE1-8144-318C2AB176E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).